CCDI case PBBYKH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/9b3e4cef-d0e9-4f52-8344-b60815234ef9

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 4.7 years (1,730 days).

Biospecimens (3 samples)
- Sample 0DKPWE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKPWN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKPWZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
